Surgical pathology report (de-identified scan), TCGA case TCGA-Y6-A9XI, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Arizona, specimen TCGA-Y6-A9XI-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report (Order)

Surgical Pathology Report

Status: Final result

Surgical
Pathology Report

Value

SURGICAL PATHOLOGY REPORT

ACCESSION NO. : [REDACTED]

Final Diagnosis(es):

(A) Bladder neck margin, biopsy: Normal prostate glands present.

(B) Prostate with seminal vesicles, radical prostatectomy:

1) Bilateral prostate adenocarcinoma, Gleason sum score 4+4 = 8/10 (see Synoptic report, below).

2) Largest nodule: 4.5 x 3.0 x 2.0 cm = 36 cc.

3) Lymphovascular and perineural invasion present.

4) Extensive bilateral capsular penetration.

Right side - slides B2, B13, B17, B21, B25, B29.

Left side - slides B5, B14, B22, B26, B30.

5) Positive right posterior lateral margin (slides B2, B9, B13).

6) Pathologic stage: pT3aNOMX

(C) Bilateral pelvic lymph nodes, excision: Four lymph nodes negative for malignancy (0/4).

Synoptic Report:

Diagnosis: Prostate adenocarcinoma, bilateral.

Procedure: Radical prostatectomy.

Specimen Size: 4.5 x 3.8 x 3.6 cm.

Specimen Weight: 40.1 gm.

Lymph Node Sampling: Pelvic lymph node dissection.

Histologic Type: Adenocarcinoma, acinar type.

Histologic Grade (Gleason pattern)

Primary Pattern: Grade 4

Secondary Pattern: Grade 4

Total Gleason Score: 4+4 = 8/10

Percent of Prostate Involved: 36 cc

Size of Dominant Nodule

Greatest dimension: 14.5 mm

Additional dimensions: 13 x 13 mm

Extraprostatic Extension: Nonfocal

Seminal Vesicle Invasion:

Left: Negative

Right: Negative

Lymphovascular Invasion: Positive

Margins: Posterolateral: Positive

Nodes: Node Group: Bilateral pelvic nodes

Total: 4

Positive: 0

Pathologic Stage: pT3aNOMX

ICD-C-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

Qx 5/30/14

[page 2 of 3]
Electronically Signed

Specimen(s) Received:

A: Posterior bladder neck margin
B: Prostate with seminal vesicles
C: Bilateral pelvic LN

Clinical History:

Prostate cancer.
(B) Tumor Bank.

Intraoperative Consultation:

Time Received:

Time Reported:

FSA1: Posterior bladder neck margin: Benign fibromuscular tissue with three glands at one end (1 block).

Gross Description:

(A) (posterior bladder neck margin) Received fresh for frozen

section analysis is a fragment of firm white-tan tissue measuring 0.3 x 0.2 cm submitted in cassette FSA1.

(B) (prostate with seminal vesicles) Received in formalin following Tumor Bank sampling, inking and orientation is a radical prostatectomy with the bilateral seminal vesicles removed and weighs 40.1 gm and is 4.5 cm right to left, 3.6 cm superior to inferior and 3.8 cm anterior to posterior. Right half is inked red, the left half is inked green and the posterior midline is inked black. The capsule appears intact.

Serial oblique sections are made and show focal tan solid nodules within both the right and left halves of the specimen.

This nodularity comprises roughly 10% of the total volume of the specimen. There is a large nodule measuring 0.5 x 0.4 cm that is abutting the capsule on the right side of the specimen at approximately levels 5-7. The remaining volume consists of pale tan rubbery trabeculated tissue. The right seminal vesicle is 5.0 x 1.8 x 0.6 cm and the vas deferens is 4.6 cm long x 0.7 cm in diameter. The left seminal vesicle is 3.9 x 1.5 x 0.9 cm and the left vas deferens is 4.5 cm long x 0.7 cm in diameter. A diagram is provided to facilitate orientation. The entire specimen is submitted as follows:

Printed by

[page 3 of 3]
B1-B7 - apex submitted right to left
B8-B39 - prostate submitted entirely
B40-B56 - bilateral seminal vesicles submitted entirely
(C) (bilateral pelvic lymph nodes) Received in formalin are multiple fragments of lobular yellow adipose tissue with firm lymph nodes measuring 5.5 x 4.0 x 1.0 cm. The specimen is palpated for nodes and submitted as follows:
C1 - one lymph node, sectioned
C2 - one lymph node, sectioned
C3 - one node

Microscopic Description:
Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(3c6), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26) Ki67(30-9).

Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per C.A.P. requirements for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are

Printed by

12/19/13

Source: NCI Genomic Data Commons file 399f136a-07ed-4d67-8e6f-a79f57b6e986 (TCGA-Y6-A9XI.FA6B58B3-B9C2-437D-9041-B0179F1386ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).